FM case AD15956 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/de449bd2-4375-49b7-99a7-96b03200d49c

Male, 58.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
